Gene-level copy-number profile of tumor specimen C3L-02704-71 (profiled together with C3L-02704-72, C3L-02704-73) from CPTAC case C3L-02704, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.4 years (19,879 days).
Specimen C3L-02704-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 180f32c3-4bab-41cf-8575-2fbe2789c518.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02704-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/605c438f-4fe1-4dea-a1c4-7c611ca93887

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 3; copy number 2: 8,113; copy number 3: 433; copy number 4: 48,203; copy number 5: 36; copy number 6: 1,988; copy number 8: 21; copy number 9: 3; copy number 10: 1; copy number 11: 1; copy number 121: 10; copy number 125: 9; copy number 131: 7; copy number 132: 3; copy number 249: 5.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:149,631,437–149,631,549, 1 gene (within-gene range 0–2): Y_RNA.
- chr6:168,441,151–169,781,600, 24 genes: SMOC2, AL136099.1, AL513210.2, AL513210.1, AL109924.3, AL109924.1, AL109924.2, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,239,002–21,321,827, 4 genes: IFNA14, IFNA22P, IFNA5, IFNA20P.
- chr9:21,367,424–21,410,185, 6 genes (within-gene range 0–2): IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8.
- chr9:21,695,176–22,214,672, 17 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:1,022,630–1,132,384, 3 genes (within-gene range 0–2): IDI2-AS1, IDI1, WDR37.
- chr10:1,361,001–1,361,637, 1 gene (within-gene range 0–2): AL513304.1.
- chr10:87,201,647–87,357,882, 5 genes (within-gene range 0–2): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 39 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene, copy number 9: AC083906.4.
- chr7:47,275,154–47,582,558, 1 gene, copy number 11: TNS3.
- chr7:50,444,128–51,729,716, 18 genes, copy number 121–249: FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P.
- chr7:53,316,149–53,366,209, 2 genes, copy number 9–10: RNF138P2, RNU1-14P.
- chr7:54,542,325–55,260,256, 13 genes, copy number 121–131: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:56,163,145–56,229,782, 3 genes, copy number 132: IFITM3P4, AC006970.1, CCNJP1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 9: AC128676.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
